Somatic mutation profile of tumor specimen HTMCP-03-06-02369-01A (aliquot HTMCP-03-06-02369-01A-01D-10409) from CGCI case HTMCP-03-06-02369, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G2.
Specimen HTMCP-03-06-02369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bea9ca10-c200-45dd-a7b3-62340cc7889d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02369-10A (Blood Derived Normal), aliquot HTMCP-03-06-02369-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59a03852-7677-43f5-a528-e9adcc5f1a38

The open-access MAF lists 152 somatic variants for this specimen: 113 protein-altering or splice-affecting, 29 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 29, Intron 8, Frame Shift Del 7, Nonsense Mutation 7, Frame Shift Ins 2, Splice Site 2, In Frame Del 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- BCHE | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 25/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs199660374, CM990287; ClinVar: likely pathogenic; called by muse, mutect2
- BRCA2 | c.658_659del p.V220Ifs*4 | Frame Shift Del (DEL) | VAF 17/101 reads (17%) | catalogued as rs80359604; ClinVar: pathogenic / risk factor; called by mutect2, pindel, varscan2
- ADGB | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776042989, COSV58858017; called by muse, mutect2, varscan2
- AHCTF1 | c.4915G>A p.E1639K (on ENST00000366508; = p.E1613K on NM_015446.5) | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58245683; called by muse, mutect2
- ARHGEF7 | c.735G>T p.E245D (on ENST00000375741 / NM_001113511.2; = p.E67D on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as COSV54548037; called by muse, mutect2, varscan2
- ARID5B | c.1718C>G p.S573* | Nonsense Mutation (SNP) | VAF 6/105 reads (6%) | catalogued as COSV54417376; called by muse, mutect2
- ARNTL | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV62987403; called by muse, mutect2, varscan2
- C2orf16 | c.5038G>T p.G1680C | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs112465116, COSV62674338; called by muse, mutect2, varscan2
- CARD11 | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV62754226; called by muse, mutect2, varscan2
- CCDC18 | c.3133dup p.I1045Nfs*3 (on ENST00000343253 / NM_001306076.1; = p.I1046Nfs*3 on NM_206886.4) | Frame Shift Ins (INS) | VAF 21/174 reads (12%) | catalogued as rs1557684985; called by mutect2, pindel, varscan2
- CHFR | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs746187833; called by muse, mutect2, varscan2
- CIAO3 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as COSV52400498; called by muse, mutect2, varscan2
- COL4A5 | c.4532G>A p.R1511H | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as rs104886285, CM003670, COSV60355867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as rs376291264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs371402883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM135B | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335175102, COSV104372835; called by muse, mutect2, varscan2
- FAT1 | c.7666C>T p.R2556* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as rs921535768, COSV71671661; called by muse, mutect2
- GABRG3 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as rs184908108; called by muse, mutect2, varscan2
- IKZF1 | c.1145del p.V382Gfs*33 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as COSV58788050; called by mutect2, pindel, varscan2
- KRTAP4-11 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs759641505, COSV66948487; called by muse, varscan2
- LCT | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV51468500; called by muse, mutect2, varscan2
- LILRB3 | c.1645G>A p.D549N (on ENST00000346401; = p.D537N on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs759831742; called by muse, mutect2, varscan2
- MAP7D3 | c.2598C>G p.I866M | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as rs755808422; called by muse, mutect2, varscan2
- MAP9 | c.916C>G p.Q306E | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.124); catalogued as rs1176862735, COSV60904252; called by muse, mutect2, varscan2
- MSN | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772365732, COSV64304935; called by muse, mutect2, varscan2
- MYH6 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 73/345 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as rs747945067, COSV62447595; called by muse, mutect2, varscan2
- NF2 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV58523413, COSV58530082, COSV58533698; called by muse, mutect2, varscan2
- NLRP5 | c.3571G>C p.D1191H | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV101173923; called by muse, mutect2, varscan2
- RAD51AP1 | c.961G>A p.V321M (on ENST00000228843 / NM_001130862.2; = p.V304M on NM_006479.5) | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV57411525; called by muse, mutect2, varscan2
- RAD51D | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376855484, CM1310352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.732); catalogued as rs748212094, COSV53466796; called by muse, mutect2, varscan2
- RYR2 | c.12292G>A p.V4098I | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.115); catalogued as rs1047248475, COSV63661279, COSV63692480; called by muse, mutect2
- SHROOM2 | c.2516C>T p.T839M | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs1255700211; called by muse, mutect2, varscan2
- SMG1 | c.2408G>A p.R803H | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs778061610, COSV67171058; called by muse, mutect2, varscan2
- SPEG | c.5311C>G p.Q1771E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs764724129; called by muse, mutect2, varscan2
- STARD8 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs772751871, COSV52933542, COSV99074103; called by muse, mutect2
- STYXL2 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs768248884, COSV54805883; called by muse, mutect2, varscan2
- TANC2 | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282488329, CM1211476; called by muse, mutect2, varscan2
- TTN | c.87049G>A p.E29017K (on ENST00000591111; = p.E21593K on NM_003319.4) | Missense Mutation (SNP) | VAF 30/147 reads (20%) | PolyPhen probably damaging (0.994); catalogued as COSV60229470; called by muse, mutect2, varscan2
- VRTN | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1027923829; called by muse, mutect2, varscan2
- VWF | c.794G>T p.C265F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54613041; called by muse, mutect2, varscan2
- ZXDB | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs1476376854; called by muse, mutect2
- ACVR2A | c.1119_1138del p.A374Cfs*30 | Frame Shift Del (DEL) | VAF 24/119 reads (20%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP12 | c.371T>C p.M124T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.091); called by muse, varscan2
- ALMS1 | c.10661T>C p.L3554S | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARHGAP6 | c.1257G>T p.Q419H | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ASXL3 | c.5314A>G p.K1772E | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ATP11C | c.2710-1G>T p.X904_splice | Splice Site (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- BANK1 | c.1692G>C p.K564N | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- CEP350 | c.708G>C p.L236F | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CLCA4 | c.2147G>A p.R716K | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2
- COL12A1 | c.6523A>G p.N2175D | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CROCC | c.1270A>C p.T424P | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- CXorf56 | c.586G>A p.A196T (on ENST00000536133 / NM_001170570.2; = p.A210T on NM_022101.4) | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2
- DMD | c.10375A>G p.I3459V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT1 | c.11085_11088del p.L3695Ffs*3 | Frame Shift Del (DEL) | VAF 36/139 reads (26%) | called by mutect2, pindel, varscan2
- FGFR4 | c.2399T>C p.V800A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by mutect2, varscan2
- FRMPD4 | c.2056_2075del p.R686Cfs*3 | Frame Shift Del (DEL) | VAF 23/212 reads (11%) | called by mutect2, pindel, varscan2
- FSIP2 | c.4211C>G p.S1404C | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- FSIP2 | c.5168C>T p.S1723L | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FSIP2 | c.5257C>T p.L1753F | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.5704C>T p.Q1902* | Nonsense Mutation (SNP) | VAF 70/230 reads (30%) | called by muse, varscan2
- FSIP2 | c.5827C>G p.Q1943E | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- HCN1 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HLA-A | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- HUWE1 | c.3789G>C p.K1263N | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- INTS6L | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IVL | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- KCNH1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0408 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 119/247 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- KIAA0586 | c.812G>A p.S271N (on ENST00000619416 / NM_001244190.2; = p.S286N on NM_014749.5) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIDINS220 | c.2197C>G p.L733V | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- KIF4B | c.608C>G p.T203R | Missense Mutation (SNP) | VAF 48/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LARS1 | c.1465G>C p.D489H (on ENST00000394434 / NM_020117.11; = p.D462H on NM_016460.3) | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- LYST | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- MBTD1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MED12L | c.1339T>C p.C447R | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MKI67 | c.3449G>T p.S1150I | Missense Mutation (SNP) | VAF 59/333 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- MUC12 | c.15022T>C p.F5008L (on ENST00000379442; = p.F4865L on NM_001164462.1) | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.48); called by muse, mutect2
- MUC16 | c.16421C>T p.T5474I | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NOTCH1 | c.2827_2837del p.E943Qfs*6 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, pindel, varscan2
- NOX1 | c.1587C>G p.F529L | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NYNRIN | c.2701C>G p.H901D | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- OCRL | c.465_479del p.F155_N159del | In Frame Del (DEL) | VAF 20/141 reads (14%) | called by mutect2, pindel, varscan2
- OTOA | c.2128A>G p.I710V (on ENST00000286149; = p.I696V on NM_144672.4) | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OTOG | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRKDC | c.2934+2T>A p.X978_splice | Splice Site (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- PTPRQ | c.2816C>G p.S939* (on ENST00000616559; = p.S897* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- RIMS1 | c.3858A>C p.L1286F | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SCFD2 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN2A | c.5022C>A p.Y1674* | Nonsense Mutation (SNP) | VAF 100/461 reads (22%) | called by muse, mutect2, varscan2
- SHROOM4 | c.570C>A p.Y190* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- SLC12A1 | c.2205dup p.Q736Tfs*47 | Frame Shift Ins (INS) | VAF 27/121 reads (22%) | called by mutect2, pindel, varscan2
- SLC17A2 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SLITRK2 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- SND1 | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- SOGA1 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SON | c.5471C>T p.S1824F | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TMEM132D | c.2450A>G p.H817R | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- TNS2 | c.2899G>A p.E967K (on ENST00000314250 / NM_170754.4; = p.E977K on NM_015319.2) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2
- TPCN1 | c.686T>A p.L229Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.3328A>C p.K1110Q (on ENST00000591111; = p.K1064Q on NM_003319.4) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | PolyPhen benign (0.046); called by muse, mutect2, varscan2
- UNC79 | c.6892G>C p.E2298Q (on ENST00000393151 / NM_001346218.2; = p.E2121Q on NM_020818.5) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- USP31 | c.4051C>A p.P1351T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- USP37 | c.1113_1116del p.Q372Vfs*61 | Frame Shift Del (DEL) | VAF 25/168 reads (15%) | called by mutect2, pindel, varscan2
- WFIKKN2 | c.1356G>T p.Q452H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- ZMYM1 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF234 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF236 | c.4183C>G p.L1395V | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ZNF536 | c.2426C>A p.A809D | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ZSCAN4 | c.5_25del p.A2_F9delinsV | In Frame Del (DEL) | VAF 10/85 reads (12%) | called by mutect2, pindel
- ABCC9 | c.2010T>C p.I670= | Silent (SNP) | VAF 27/118 reads (23%) | called by muse, mutect2, varscan2
- ANO2 | c.1770C>T p.L590= (on ENST00000356134 / NM_001278597.3; = p.L594= on NM_001278596.3) | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs1484004567; called by muse, mutect2, varscan2
- CACNA1G | c.519C>T p.N173= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs765688404; called by muse, varscan2
- CHD9 | c.6579A>G p.S2193= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- CIP2A | c.2580A>G p.L860= | Silent (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- CR2 | c.2178C>G p.V726= | Silent (SNP) | VAF 35/225 reads (16%) | called by muse, mutect2, varscan2
- CTC1 | c.141G>A p.K47= | Silent (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- CUL3 | c.2148G>A p.K716= | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- FBN1 | c.5805A>G p.A1935= | Silent (SNP) | VAF 24/141 reads (17%) | called by muse, mutect2, varscan2
- FLNA | c.5433C>G p.P1811= (on ENST00000369850 / NM_001110556.2; = p.P1803= on NM_001456.3) | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- GFRA1 | c.801C>T p.C267= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as COSV62608837; called by muse, mutect2, varscan2
- HERC1 | c.11205A>T p.S3735= | Silent (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- KIAA1217 | c.2868G>T p.V956= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100287244; called by muse, mutect2, varscan2
- KNDC1 | c.4029G>A p.G1343= | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, varscan2
- NCOA6 | c.4800T>C p.F1600= | Silent (SNP) | VAF 17/320 reads (5%) | called by muse, mutect2
- NPAS2 | c.1899G>A p.P633= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs780286248, COSV59558865; called by muse, mutect2, varscan2
- PCDHA5 | c.1551C>T p.Y517= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs782587996, COSV65349128, COSV65350259; called by muse, mutect2, varscan2
- PCDHB16 | c.939G>A p.T313= | Silent (SNP) | VAF 62/390 reads (16%) | catalogued as rs1244265805, COSV53371780; called by muse, mutect2, varscan2
- PLCH1 | c.4593G>A p.V1531= (on ENST00000340059 / NM_001130960.2; = p.V1523= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/357 reads (15%) | called by muse, mutect2, varscan2
- SCN2A | c.2322C>G p.L774= | Silent (SNP) | VAF 35/187 reads (19%) | catalogued as COSV51835706, COSV51838016; called by muse, mutect2, varscan2
- SI | c.1650G>A p.Q550= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- SLC39A6 | c.1074G>C p.L358= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV99309493; called by muse, mutect2, varscan2
- SLC44A5 | c.2016A>G p.A672= | Silent (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- SOS1 | c.3801C>T p.H1267= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as rs747676700; ClinVar: likely benign; called by muse, mutect2, varscan2
- TARBP1 | c.3936G>T p.L1312= | Silent (SNP) | VAF 21/192 reads (11%) | called by muse, mutect2
- TMEFF2 | c.186A>G p.R62= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV55835801; called by muse, mutect2, varscan2
- TMEM132D | c.2274G>A p.A758= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as rs764134740, COSV67159169; called by muse, mutect2, varscan2
- VPS13C | c.1923C>G p.V641= (on ENST00000644861 / NM_020821.3; = p.V598= on NM_017684.5) | Silent (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2, varscan2
- ZNF804A | c.3303T>A p.T1101= | Silent (SNP) | VAF 61/203 reads (30%) | catalogued as COSV56452085; called by muse, mutect2, varscan2
- AC133485.7 | n.2152G>A | RNA (SNP) | VAF 16/288 reads (6%) | catalogued as rs571804158; called by muse, mutect2
- ANKRD30BL | chr2:132147633 T>C | 3'Flank (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- ANO6 | c.71-31551T>C | Intron (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- DLG2 | c.205-65564C>A | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- GRAMD1B | c.234+842C>T | Intron (SNP) | VAF 60/297 reads (20%) | catalogued as COSV59206841; called by muse, mutect2, varscan2
- IFNGR1 | c.85+3930G>A | Intron (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- LMBR1L | c.157+218C>T | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- RFPL2 | c.266-88C>T | Intron (SNP) | VAF 21/145 reads (14%) | catalogued as rs3959624; called by muse, mutect2, varscan2
- TTN | c.10361-3904A>G | Intron (SNP) | VAF 33/172 reads (19%) | catalogued as rs1460265761, COSV60178147; called by muse, mutect2, varscan2
- UNC5A | c.293-2429A>G | Intron (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
